Gene-level copy-number profile of tumor specimen REBC-ADKM-TTP1-A from REBC case REBC-ADKM, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADKM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0867a435-7d23-436d-9d66-0bdebc4796a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADKM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/80cb4985-9e24-4fb1-be01-bb13ff693c55

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 47; copy number 2: 58,225; copy number 3: 60; copy number 4: 67; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:98,706,236–98,821,201, 3 genes, copy number 5 (within-gene range 2–5): ST3GAL6-AS1, ST3GAL6, PDLIM1P4.
- chr3:98,804,978–98,805,084, 1 gene, copy number 5 (within-gene range 2–5): RNU6-26P.
- chr15:85,178,628–85,178,806, 1 gene, copy number 5: AC044860.2.
- chr15:85,181,210–85,182,083, 1 gene, copy number 5: NIFKP8.

Autosomal genes at a single copy (total copy number 1): 47. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
